FM case AD4815 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/90181d8c-b07d-4140-8dfd-6817c4a703ac

Female, 82.8 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the vulva. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
